Somatic mutation profile of tumor specimen TCGA-29-2432-01A (aliquot TCGA-29-2432-01A-01D-1526-09) from TCGA case TCGA-29-2432, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.9 years (22,605 days).
Specimen TCGA-29-2432-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7027d29-1f33-4468-8b37-8a207b87c7e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-2432-10A (Blood Derived Normal), aliquot TCGA-29-2432-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ba83ad2-2f36-4448-87e9-ddb63170896b

The open-access MAF lists 99 somatic variants for this specimen: 68 protein-altering or splice-affecting, 26 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 26, Frame Shift Del 4, Nonsense Mutation 3, Intron 3, Splice Site 2, In Frame Del 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PEX1 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 63/415 reads (15%) | catalogued as rs61750409, CM015843, COSV99951959; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 100/186 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as COSV64670875, COSV64676929; called by muse, mutect2, varscan2
- ABCC6 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 58/504 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52741066; called by muse, mutect2, varscan2
- AGMO | c.490G>C p.V164L | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV61105271; called by muse, mutect2, varscan2
- AP1G2 | c.1892A>G p.D631G | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763511307, COSV55337264; called by muse, mutect2, varscan2
- ATMIN | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV55145072; called by muse, mutect2, varscan2
- BAIAP3 | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV50103509; called by muse, mutect2, varscan2
- BTN3A1 | c.128T>C p.M43T | Missense Mutation (SNP) | VAF 144/937 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV50024431; called by muse, mutect2, varscan2
- C2CD3 | c.3839C>G p.A1280G | Missense Mutation (SNP) | VAF 87/382 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV58089263; called by muse, mutect2, varscan2
- CATSPERE | c.2209C>G p.P737A | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV63675703; called by muse, mutect2, varscan2
- CFAP61 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as rs371474647; called by muse, mutect2, varscan2
- CPSF1 | c.2683G>T p.V895F | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as COSV100450286; called by muse, mutect2
- CTSF | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 319/438 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs757455465, COSV59747341; called by muse, mutect2, varscan2
- DNAH8 | c.2606+2C>G p.X869_splice | Splice Site (SNP) | VAF 56/144 reads (39%) | catalogued as rs1285385539, COSV59423134; called by muse, mutect2, varscan2
- DPP10 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs764715614, COSV59662512; called by muse, mutect2, varscan2
- EIF2B4 | c.1369C>G p.L457V (on ENST00000347454 / NM_001034116.2; = p.L456V on NM_015636.3) | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV61456064; called by muse, mutect2, varscan2
- EIF3D | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99341409; called by muse, mutect2, varscan2
- EPHA4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 78/812 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs1250363178, COSV99915938; called by muse, mutect2
- EXO1 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62216198; called by muse, mutect2, varscan2
- FGD4 | c.891G>C p.K297N | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56780061; called by muse, mutect2, varscan2
- FRRS1L | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199731037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GJD4 | c.649G>T p.V217F | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV58701880; called by muse, mutect2, varscan2
- GSN | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 47/431 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.425); catalogued as COSV57994436; called by muse, mutect2, varscan2
- GTF2H4 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs767371516, COSV52559090; called by muse, mutect2
- IL21R | c.133A>C p.S45R | Missense Mutation (SNP) | VAF 306/856 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV61968311; called by muse, mutect2, varscan2
- INPP5F | c.1539C>G p.S513R | Missense Mutation (SNP) | VAF 107/468 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62819507; called by muse, mutect2, varscan2
- KPRP | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 79/280 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV64220894; called by muse, mutect2, varscan2
- KRTAP6-3 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | PolyPhen benign (0.037); catalogued as COSV66962629; called by muse, mutect2, varscan2
- MAP3K5 | c.2365G>T p.E789* | Nonsense Mutation (SNP) | VAF 105/274 reads (38%) | catalogued as COSV62886832; called by muse, mutect2, varscan2
- MTA1 | c.1069C>G p.P357A | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58755462; called by muse, mutect2, varscan2
- NPSR1 | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 146/837 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as COSV62196116; called by muse, mutect2, varscan2
- NSD1 | c.3959G>A p.R1320Q | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1388537733, COSV61770292; called by muse, mutect2, varscan2
- OGFR | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV51696452; called by muse, mutect2, varscan2
- OR2M2 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV62897726, COSV62897788; called by muse, mutect2, varscan2
- PAPPA | c.1642C>G p.P548A | Missense Mutation (SNP) | VAF 107/428 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771250253, COSV60277028; called by muse, mutect2, varscan2
- PCDHB8 | c.1217C>G p.T406R | Missense Mutation (SNP) | VAF 135/1102 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV50753660, COSV99176931; called by muse, mutect2, varscan2
- PDE7A | c.833C>T p.T278I (on ENST00000401827 / NM_001242318.3; = p.T252I on NM_002603.4) | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs997564440, COSV65152141; called by muse, mutect2, varscan2
- PER3 | c.2567del p.P856Lfs*32 | Frame Shift Del (DEL) | VAF 17/171 reads (10%) | catalogued as rs752424798, COSV62706362; called by mutect2, pindel, varscan2
- PIGO | c.2239G>T p.V747L | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV53052332; called by muse, mutect2, varscan2
- PRKCB | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 242/464 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs774746011, COSV57764894; called by muse, mutect2, varscan2
- PROKR2 | c.432T>A p.N144K | Missense Mutation (SNP) | VAF 77/352 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54085095; called by muse, mutect2, varscan2
- QTRT2 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 77/524 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556393060, COSV55558622; called by muse, mutect2, varscan2
- RAB9A | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV54610470; called by muse, mutect2, varscan2
- RASSF4 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58484333; called by muse, mutect2, varscan2
- RFT1 | c.1423T>G p.F475V | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV56247934; called by muse, mutect2, varscan2
- RORC | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272363264, COSV59091146; called by muse, mutect2, varscan2
- SLC2A7 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 67/414 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68901263; called by muse, mutect2, varscan2
- SLC8A1 | c.1292G>T p.R431L | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV60470187, COSV60474519; called by muse, mutect2, varscan2
- SPTB | c.5984A>G p.N1995S | Missense Mutation (SNP) | VAF 73/362 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV67629678; called by muse, mutect2, varscan2
- SPTBN4 | c.785-1G>C p.X262_splice | Splice Site (SNP) | VAF 50/244 reads (20%) | catalogued as COSV58943156; called by muse, mutect2, varscan2
- STK25 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420940006, COSV50868886, COSV99885756; called by muse, mutect2, varscan2
- STOML2 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV59714900; called by muse, mutect2, varscan2
- SYCP2 | c.3505T>A p.F1169I | Missense Mutation (SNP) | VAF 122/383 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62765721; called by muse, mutect2, varscan2
- TACC2 | c.6073G>A p.D2025N (on ENST00000334433; = p.D103N on NM_006997.4) | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773774461, COSV53277076, COSV53278918; called by muse, mutect2
- TMEM161A | c.369C>G p.Y123* | Nonsense Mutation (SNP) | VAF 181/304 reads (60%) | catalogued as COSV50776177; called by muse, mutect2, varscan2
- TRPM3 | c.506T>C p.L169P (on ENST00000357533 / NM_001366142.2; = p.L14P on NM_020952.6) | Missense Mutation (SNP) | VAF 64/445 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV62467197; called by muse, mutect2, varscan2
- TYRP1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as rs139670838; called by muse, mutect2, varscan2
- UGT1A9 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV60844621; called by muse, mutect2
- VCL | c.2105G>C p.W702S | Missense Mutation (SNP) | VAF 27/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99280578; called by muse, mutect2
- VDR | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs749838232, COSV57466751; called by muse, mutect2, varscan2
- WDR6 | c.1075T>A p.S359T | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV58243820; called by muse, mutect2, varscan2
- ZNF250 | c.1659C>G p.H553Q | Missense Mutation (SNP) | VAF 77/819 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99480725; called by muse, mutect2
- ZNF607 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 494/737 reads (67%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV62206046, COSV67696082; called by muse, mutect2, varscan2
- CD163L1 | c.1382_1383del p.R461Ifs*9 | Frame Shift Del (DEL) | VAF 19/135 reads (14%) | called by mutect2, pindel, varscan2
- GP2 | c.1188_1215del p.V397Lfs*8 (on ENST00000381362 / NM_001007240.3; = p.V394Lfs*8 on NM_001502.4) | Frame Shift Del (DEL) | VAF 130/1259 reads (10%) | called by mutect2, pindel
- PANX1 | c.1097del p.L366Pfs*2 | Frame Shift Del (DEL) | VAF 38/204 reads (19%) | called by mutect2, pindel, varscan2
- PSD2 | c.276_284del p.D92_A94del | In Frame Del (DEL) | VAF 37/333 reads (11%) | called by mutect2, pindel, varscan2
- AKAP6 | c.3378C>G p.L1126= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV99799227; called by muse, mutect2
- C10orf90 | c.1890T>G p.P630= | Silent (SNP) | VAF 124/641 reads (19%) | catalogued as COSV52949049; called by muse, mutect2, varscan2
- COL4A6 | c.4347G>A p.G1449= | Silent (SNP) | VAF 35/192 reads (18%) | catalogued as rs765691496, COSV57858837; called by muse, mutect2, varscan2
- CYTH2 | c.552G>A p.T184= | Silent (SNP) | VAF 55/263 reads (21%) | catalogued as rs61497330, COSV100287081; called by muse, mutect2, varscan2
- EHBP1 | c.3240A>T p.A1080= | Silent (SNP) | VAF 47/234 reads (20%) | catalogued as COSV50415617; called by muse, mutect2, varscan2
- EN1 | c.387T>C p.A129= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1396028551, COSV99727036; called by muse, mutect2
- FXR1 | c.1329A>T p.G443= | Silent (SNP) | VAF 241/611 reads (39%) | catalogued as COSV59760852; called by muse, mutect2, varscan2
- GPRIN3 | c.2244G>A p.R748= | Silent (SNP) | VAF 55/271 reads (20%) | catalogued as COSV60884003; called by muse, mutect2, varscan2
- IP6K2 | c.774C>T p.G258= | Silent (SNP) | VAF 89/328 reads (27%) | catalogued as COSV53659561; called by muse, mutect2, varscan2
- LTBP1 | c.1569C>T p.Y523= (on ENST00000404816 / NM_206943.4; = p.Y197= on NM_000627.4) | Silent (SNP) | VAF 65/321 reads (20%) | catalogued as COSV63179260; called by muse, mutect2, varscan2
- MAP3K9 | c.342C>T p.R114= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV67119770; called by muse, mutect2, varscan2
- MAPKBP1 | c.1200G>A p.E400= (on ENST00000456763 / NM_001128608.2; = p.E394= on NM_014994.3) | Silent (SNP) | VAF 64/309 reads (21%) | catalogued as COSV52957895; called by muse, mutect2, varscan2
- NUP205 | c.2601A>G p.L867= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV53654594; called by muse, mutect2, varscan2
- OLFM1 | c.438C>T p.H146= (on ENST00000371793 / NM_001282611.2; = p.H128= on NM_006334.4) | Silent (SNP) | VAF 656/1008 reads (65%) | catalogued as rs769511587, COSV52961466; called by muse, mutect2, varscan2
- OR10J5 | c.564C>T p.C188= | Silent (SNP) | VAF 94/254 reads (37%) | catalogued as COSV58384766; called by muse, mutect2, varscan2
- P2RX7 | c.1551C>G p.V517= | Silent (SNP) | VAF 146/221 reads (66%) | catalogued as COSV55853198; called by muse, mutect2, varscan2
- PCED1B | c.546G>T p.R182= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV71394858; called by muse, mutect2, varscan2
- PKHD1 | c.5508C>T p.Y1836= | Silent (SNP) | VAF 44/560 reads (8%) | catalogued as COSV100581802; called by muse, mutect2
- PPIG | c.1611A>G p.E537= | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as COSV53640780; called by muse, mutect2, varscan2
- RNF213 | c.63C>T p.C21= | Silent (SNP) | VAF 88/211 reads (42%) | catalogued as rs775062705, COSV60618654; called by muse, mutect2, varscan2
- RPS6KA6 | c.1950C>T p.D650= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV53115800; called by muse, mutect2, varscan2
- STAB1 | c.5994T>C p.R1998= | Silent (SNP) | VAF 86/440 reads (20%) | catalogued as COSV58731801; called by muse, mutect2, varscan2
- STXBP1 | c.390G>T p.L130= | Silent (SNP) | VAF 111/663 reads (17%) | catalogued as COSV64811992; called by muse, mutect2, varscan2
- TBC1D9B | c.7C>T p.L3= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs777049753, COSV62280990; called by muse, mutect2, varscan2
- UBR4 | c.7707G>A p.V2569= | Silent (SNP) | VAF 76/451 reads (17%) | catalogued as COSV64382513; called by muse, mutect2, varscan2
- VPS50 | c.885A>G p.L295= | Silent (SNP) | VAF 115/617 reads (19%) | catalogued as COSV52492403; called by muse, mutect2, varscan2
- ATXN2L | c.*209G>C | 3'UTR (SNP) | VAF 19/116 reads (16%) | catalogued as COSV57364853; called by muse, mutect2, varscan2
- DOCK8 | chr9:214631 G>C | 5'Flank (SNP) | VAF 12/52 reads (23%) | catalogued as COSV66687944; called by muse, mutect2
- ERCC6 | c.1397+7344C>A | Intron (SNP) | VAF 119/304 reads (39%) | catalogued as COSV63387741; called by muse, mutect2, varscan2
- TMEM71 | c.814+145C>A | Intron (SNP) | VAF 44/522 reads (8%) | catalogued as COSV63456651; called by muse, mutect2
- VPS13B | c.4820+15684G>C | Intron (SNP) | VAF 90/679 reads (13%) | catalogued as COSV62132381; called by muse, mutect2, varscan2
